HCMI case HCM-WCMC-0673-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0bcca666-3c62-4eb9-a47c-93bb7c020ad6

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1986.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 32.9 years (12,015 days); AJCC staging edition: 8th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Prior malignancy: no; Prior treatment: Yes; Residual disease: R1; Ovarian specimen status: Ovarian Capsule Ruptured; Ovarian surface involvement: Indeterminate; Sites of involvement: Uterus / Abdominal Peritoneum / Vagina.
   Pathology details: Largest extrapelvic peritoneal focus: Macroscopic (2cm or less); Lymph nodes positive: 0; Lymph nodes tested: 0; Tumor largest dimension diameter: 10.7 cm.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant; Days to treatment start: 37 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 142 days; Days to treatment end: 142 days.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.
2. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Prior malignancy: no; Residual disease: R1; Ovarian specimen status: Ovarian Capsule Ruptured; Ovarian surface involvement: Indeterminate; Sites of involvement: Uterus / Abdominal Peritoneum / Vagina.
   Pathology details: Largest extrapelvic peritoneal focus: Macroscopic (2cm or less); Lymph nodes positive: 0; Lymph nodes tested: 0; Tumor largest dimension diameter: 5.2 cm.

Follow-up (4 entries)
- Days to follow up: 0 days; Procedures performed: Colonoscopy.
- Days to follow up: 97 days; Procedures performed: Colonoscopy.
- Days to follow up: 1,189 days (3.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 196.

Molecular and laboratory tests
- CA-125: 36.
- CA-125: 59.
- CDX2 (IHC): Negative.
- KRT20 (IHC): Positive.
- KRT7 (IHC): Positive.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PAX8 (IHC): Negative.
- PMS2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 152.4 cm; BMI: 28.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Ovarian Cancer.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0673-C56-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0673-C56-01A-S1-HE: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 3; Percent necrosis: 2; Percent stromal cells: 45; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 8.
- Sample HCM-WCMC-0673-C56-05A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0673-C56-05A-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 45; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0673-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0673-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
- Sample HCM-WCMC-0673-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 5.
- Samples HCM-WCMC-0673-C56-86A, HCM-WCMC-0673-C56-86B (2 with the same recorded description): Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
